Somatic mutation profile of tumor specimen HTMCP-03-06-02189-01A (aliquot HTMCP-03-06-02189-01A-01D-6194) from CGCI case HTMCP-03-06-02189, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3.
Specimen HTMCP-03-06-02189-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bf7770d-eb6d-47e6-893c-1d5fe58abead.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02189-10A (Blood Derived Normal), aliquot HTMCP-03-06-02189-10A-01D-6194; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7df02378-e9c4-4e58-8b6e-01df63d0274e

The open-access MAF lists 72 somatic variants for this specimen: 49 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 20, Nonsense Mutation 3, Intron 2, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs1365490247, CM158285; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMC2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 44/86 reads (51%) | catalogued as rs80356683, CM941035, COSV51458441; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.401G>A p.R134K (on ENST00000340800 / NM_022977.2; = p.R93K on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100538673; called by muse, mutect2, varscan2
- ADGB | c.4522C>T p.R1508W | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs188106474, COSV58846840; called by muse, mutect2, varscan2
- ANK2 | c.7006G>A p.A2336T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs1564016699; called by muse, mutect2, varscan2
- ARHGAP35 | c.2855A>G p.H952R | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs1011708686; called by muse, mutect2
- ARID1B | c.6182C>T p.S2061L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs149978361; called by muse, mutect2, varscan2
- CNTN6 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs369254276; called by muse, mutect2, varscan2
- DHX9 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1049265, COSV62360267; called by muse, mutect2, varscan2
- GABRG3 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.547); catalogued as rs1255738541, COSV61512989; called by muse, mutect2, varscan2
- JCAD | c.3568G>A p.E1190K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as rs758055788, COSV64761355; called by muse, mutect2, varscan2
- PCM1 | c.4004C>T p.S1335L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1248662640; called by muse, mutect2, varscan2
- PTPRM | c.4141G>A p.G1381R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs1372831979; called by muse, mutect2
- RAD51C | c.772C>G p.R258G | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA1 | c.3011T>A p.I1004N | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1327517788; called by muse, mutect2, varscan2
- SPANXD | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs373150100, COSV65152575; called by muse, varscan2
- ST18 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV52486686; called by muse, mutect2, varscan2
- TENM1 | c.5102C>T p.T1701M | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs377115628, COSV100949849; called by muse, mutect2, varscan2
- UNC13C | c.1745C>T p.S582L | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs541524342, COSV52855564; called by muse, mutect2, varscan2
- UNC13C | c.4855C>G p.Q1619E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99524333; called by muse, mutect2, varscan2
- WDR17 | c.3455C>T p.T1152M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs749386548, COSV99708315; called by mutect2, varscan2
- ALPK3 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASMT | c.1008del p.I337Ffs*6 (on ENST00000381229; = p.I365Ffs*6 on NM_004043.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- C11orf80 | c.1640_1657del p.G547_E552del | In Frame Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- CCDC168 | c.17108T>A p.M5703K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CDH13 | c.787A>T p.T263S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.109); called by mutect2, varscan2
- DNMBP | c.3713T>C p.F1238S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- EPHB1 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRAS1 | c.1535-1G>C p.X512_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- GREB1L | c.385T>A p.L129M | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC5 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ICE1 | c.6394A>T p.T2132S | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KDM5A | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- KNL1 | c.4468G>A p.E1490K (on ENST00000346991 / NM_170589.5; = p.E1464K on NM_144508.5) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LRP6 | c.4705C>A p.P1569T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBAS | c.877dup p.V293Gfs*31 | Frame Shift Ins (INS) | VAF 46/235 reads (20%) | called by mutect2, pindel, varscan2
- NPC1L1 | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2
- OSCP1 | c.463G>C p.E155Q (on ENST00000356637 / NM_001330493.1; = p.E145Q on NM_145047.5) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- PLXNB2 | c.5486C>A p.A1829D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- PPP1R9A | c.1801C>G p.Q601E | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- PRKCI | c.376C>G p.R126G | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROCK1 | c.1636C>T p.Q546* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- RTL9 | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOGA1 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- TENM1 | c.7462A>T p.N2488Y | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- UHRF1BP1 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 193/228 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- USP19 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UVRAG | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ZSWIM6 | c.2538A>T p.K846N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ARHGAP21 | c.4215C>T p.S1405= | Silent (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- CCDC150 | c.1683C>T p.N561= | Silent (SNP) | VAF 43/67 reads (64%) | catalogued as rs143780850; called by muse, mutect2, varscan2
- CDH10 | c.1008C>T p.L336= | Silent (SNP) | VAF 27/176 reads (15%) | catalogued as rs1010395181, COSV100051593, COSV52584313; called by muse, mutect2, varscan2
- CMYA5 | c.4617G>A p.K1539= | Silent (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- CUL7 | c.4266G>A p.L1422= | Silent (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- DGKI | c.1974A>G p.G658= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV55972316; called by muse, mutect2, varscan2
- DMXL2 | c.1770C>T p.H590= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as rs758709476, COSV51841840; called by muse, mutect2, varscan2
- FMR1 | c.412C>A p.R138= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as rs782759579; called by muse, mutect2
- HCN1 | c.2640C>T p.D880= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs768551046, COSV57506534; called by muse, mutect2, varscan2
- LRCH3 | c.1797T>G p.A599= | Silent (SNP) | VAF 53/250 reads (21%) | catalogued as COSV58392559; called by muse, mutect2, varscan2
- PCK1 | c.330C>T p.L110= | Silent (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- PUM2 | c.2538G>A p.Q846= | Silent (SNP) | VAF 171/404 reads (42%) | called by muse, mutect2, varscan2
- RPTOR | c.141G>A p.Q47= | Silent (SNP) | VAF 47/86 reads (55%) | catalogued as COSV100154746; called by muse, mutect2, varscan2
- RYR3 | c.12492C>G p.L4164= (on ENST00000389232; = p.L4165= on NM_001036.6) | Silent (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- SDC3 | c.903C>T p.I301= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs750648373; called by muse, mutect2, varscan2
- SMCHD1 | c.2472G>A p.E824= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV55260012; called by muse, mutect2, varscan2
- VWF | c.5874C>T p.I1958= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs773406142; called by muse, mutect2, varscan2
- ZFHX3 | c.2055C>T p.T685= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV51706714; called by muse, mutect2, varscan2
- ZNF341 | c.279C>T p.I93= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- ZNF462 | c.4782C>T p.I1594= | Silent (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- ANKRD31 | c.3424+1874G>A | Intron (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- GTF3C1 | c.4083+485G>A | Intron (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40525379 A>T | 5'Flank (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
